Somatic mutation profile of tumor specimen 0DZQ8T from CCDI case PBCSVE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 4.0 years (1,469 days).
Specimen 0DZQ8T: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 445464df-aa21-4c8a-98e1-44273da241f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZQ8O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdd2ae1e-b402-4cdf-9b45-1136cfdf919b

The open-access MAF lists 33 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 5, Intron 3, 5'UTR 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM32 | c.1966C>T p.R656C | Missense Mutation (SNP) | VAF 98/1118 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as rs1472803470, COSV65948017; called by muse, mutect2
- CEACAM7 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 39/458 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs539835752; called by muse, mutect2
- DICER1 | c.5532G>C p.K1844N | Missense Mutation (SNP) | VAF 34/969 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1360182417; called by muse, mutect2
- GRIK3 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 37/329 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.138); catalogued as rs773455615, COSV66144348, COSV66145530; called by muse, mutect2, varscan2
- HPS3 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 90/1002 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs752988768, COSV56055188; called by muse, mutect2
- KIF22 | c.1817G>T p.S606I | Missense Mutation (SNP) | VAF 53/658 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV99360940; called by muse, mutect2
- MFSD2B | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 62/482 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776859482; called by muse, mutect2, varscan2
- MYO7A | c.2440C>T p.R814C | Missense Mutation (SNP) | VAF 65/521 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1265801629; called by muse, mutect2, varscan2
- OR56A5 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 171/1355 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.993); catalogued as rs778078804, COSV60827030; called by muse, mutect2, varscan2
- PTPN11 | c.1504T>C p.S502P | Missense Mutation (SNP) | VAF 101/825 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as CM022450, CM055504, COSV61005465, COSV61007751, COSV61015981; called by muse, mutect2, varscan2
- SIGLEC1 | c.4583G>A p.R1528H | Missense Mutation (SNP) | VAF 41/494 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.061); catalogued as rs369409955; called by muse, mutect2
- USF3 | c.6621G>A p.M2207I | Missense Mutation (SNP) | VAF 76/716 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.192); catalogued as rs772572163; called by muse, mutect2, varscan2
- BMS1 | c.3268C>G p.L1090V | Missense Mutation (SNP) | VAF 119/1164 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- CCDC168 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 27/725 reads (4%) | called by muse, mutect2
- ERP27 | c.690C>G p.D230E | Missense Mutation (SNP) | VAF 90/726 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- KALRN | c.2662C>A p.Q888K | Missense Mutation (SNP) | VAF 71/650 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MYBL1 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 56/844 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- N6AMT1 | c.102C>A p.D34E | Missense Mutation (SNP) | VAF 77/534 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- SMOC1 | c.760G>T p.G254W | Missense Mutation (SNP) | VAF 56/484 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ST8SIA2 | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 90/1142 reads (8%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- TNIK | c.2751C>G p.H917Q | Missense Mutation (SNP) | VAF 92/754 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- TRRAP | c.6163G>T p.A2055S (on ENST00000359863 / NM_001244580.1; = p.A2037S on NM_003496.3) | Missense Mutation (SNP) | VAF 94/1239 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2
- TSPAN13 | c.430T>A p.C144S | Missense Mutation (SNP) | VAF 71/678 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C5orf38 | c.99G>A p.P33= | Silent (SNP) | VAF 28/279 reads (10%) | catalogued as COSV57412608; called by muse, mutect2, varscan2
- NCOR2 | c.6814C>T p.L2272= | Silent (SNP) | VAF 117/828 reads (14%) | called by muse, mutect2, varscan2
- PRUNE2 | c.4575C>T p.A1525= | Silent (SNP) | VAF 73/599 reads (12%) | catalogued as rs766558013, COSV65038889; called by muse, mutect2, varscan2
- SLC11A2 | c.654C>T p.T218= (on ENST00000394904 / NM_001379455.1; = p.T189= on NM_000617.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 90/716 reads (13%) | called by muse, mutect2, varscan2
- ZBTB7A | c.645C>T p.N215= | Silent (SNP) | VAF 40/440 reads (9%) | catalogued as rs780393207; called by muse, mutect2
- AC007342.3 | chr16:53365971 C>T | 3'Flank (SNP) | VAF 63/649 reads (10%) | catalogued as rs1397648501; called by muse, mutect2, varscan2
- CCL3 | c.74-50C>A | Intron (SNP) | VAF 29/260 reads (11%) | called by muse, mutect2, varscan2
- CEP43 | c.301-89T>C | Intron (SNP) | VAF 11/188 reads (6%) | called by muse, mutect2
- MAEA | c.70-2371T>C | Intron (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- PDPN | c.-2C>T | 5'UTR (SNP) | VAF 100/792 reads (13%) | catalogued as rs1176937193; called by muse, mutect2, varscan2
